Somatic mutation profile of tumor specimen TCGA-DU-6395-01A (aliquot TCGA-DU-6395-01A-12D-1705-08) from TCGA case TCGA-DU-6395, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 31.7 years (11,584 days).
Specimen TCGA-DU-6395-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63faf225-7f90-4be3-bbf0-b26d1df86527.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6395-10A (Blood Derived Normal), aliquot TCGA-DU-6395-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d24f91b3-4da9-4c65-9f70-578760c6845f

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 9, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 31/85 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.428T>G p.V143G | Missense Mutation (SNP) | VAF 24/60 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555526241, CM1511132, COSV52737174, COSV52760297, COSV52868891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057523496, COSV52819746, COSV53616876; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.1971del p.R658Vfs*2 | Frame Shift Del (DEL) | VAF 131/211 reads (62%) | catalogued as COSV100969978; called by mutect2, pindel, varscan2
- CDH4 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as rs187981909; called by muse, mutect2, varscan2
- DLC1 | c.3488C>T p.T1163M (on ENST00000276297 / NM_001348081.2; = p.T726M on NM_006094.5) | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775125308, COSV99364146; called by muse, mutect2, varscan2
- FAT3 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs200399875, COSV99964012; called by muse, mutect2, varscan2
- SYNE2 | c.2429C>G p.T810S | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs377493238; called by muse, mutect2, varscan2
- TBC1D9 | c.3421C>T p.R1141W | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV101464278; called by muse, mutect2, varscan2
- COL2A1 | c.3428G>A p.G1143D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COQ10B | c.677T>C p.I226T | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- DNAH8 | c.10372A>T p.I3458F | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ELAPOR2 | c.1832C>G p.S611C (on ENST00000450689 / NM_001142749.3; = p.S444C on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- N6AMT1 | c.263A>G p.E88G | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NLGN2 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PDIK1L | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- SCAI | c.1493G>A p.G498D (on ENST00000336505 / NM_001144877.3; = p.G521D on NM_173690.5) | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TEX15 | c.4424A>G p.Y1475C (on ENST00000256246; = p.Y1858C on NM_001350162.2) | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AC008397.2 | c.1182C>T p.A394= | Silent (SNP) | VAF 51/137 reads (37%) | catalogued as rs149723522; called by muse, mutect2, varscan2
- ATP8A2 | c.966C>A p.G322= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- CHRNA3 | c.1377T>C p.N459= | Silent (SNP) | VAF 31/137 reads (23%) | called by muse, mutect2, varscan2
- DLGAP1 | c.492C>T p.N164= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as rs1054343747, COSV59784598; called by muse, mutect2, varscan2
- DNAH8 | c.10371T>A p.I3457= | Silent (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2
- IGLV5-37 | c.216C>T p.Y72= | Silent (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- SHPRH | c.4671A>G p.Q1557= (on ENST00000275233 / NM_001042683.3; = p.Q1561= on NM_173082.3) | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- TP53 | c.324T>G p.G108= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV52696249, COSV52809607; called by muse, mutect2, varscan2
- UBR5 | c.423A>G p.G141= | Silent (SNP) | VAF 87/190 reads (46%) | called by muse, mutect2, varscan2
- PPP3R2 | c.-6T>G | 5'UTR (SNP) | VAF 24/74 reads (32%) | called by muse, mutect2, varscan2
